Gene-level copy-number profile of tumor specimen TCGA-29-1692-02A from TCGA case TCGA-29-1692, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 58.0 years (21,193 days).
Specimen TCGA-29-1692-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.90cade38-c7fd-407c-aba9-72c9dbc53a5e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1692-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 403 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file.
https://portal.gdc.cancer.gov/files/63879014-4d4d-4f0d-923d-de1018606238

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 372; copy number 1: 7,452; copy number 2: 21,454; copy number 3: 19,984; copy number 4: 5,322; copy number 5: 3,861; copy number 6: 1,159; copy number 7: 538; copy number 8: 32; copy number 9: 2; copy number 11: 44.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr5:55,738,017–56,606,232, 26 genes: DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1.
- chr9:96,313,444–96,421,129, 5 genes: SLC35D2, ZNF367, NSA2P7, AL133477.1, AL133477.2.
- chr14:96,019,484–96,093,971, 2 genes: AL137190.1, C14orf132.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,636 genes in 51 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,126,974–120,914,238, 17 genes, copy number 5: RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr1:143,541,768–147,056,593, 113 genes, copy number 7 (broad region; genes not listed).
- chr2:14,705,668–30,897,387, 302 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:45,168,583–45,211,673, 3 genes, copy number 5 (within-gene range 4–5): AC093833.1, AC009236.2, AC009236.1.
- chr2:186,486,253–186,509,361, 2 genes, copy number 6: ZC3H15, DPRXP1.
- chr2:241,477,905–241,558,977, 4 genes, copy number 6 (within-gene range 2–6): MIR3133, KCTD5P1, STK25, BOK-AS1.
- chr3:26,622,806–33,492,098, 89 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:141,324,213–156,539,138, 250 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr3:156,215,560–165,846,519, 110 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:173,910,498–198,222,513, 503 genes, copy number 5–8 (broad region; genes not listed).
- chr5:58,198–32,791,724, 496 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:44,742,420–45,895,970, 10 genes, copy number 6: MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:905,445–1,613,897, 15 genes, copy number 5: AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1.
- chr6:42,727,234–42,948,360, 10 genes, copy number 5: ATP6V0CP3, TBCC, BICRAL, RPL7L1, C6orf226, AL035587.3, PTCRA, AL035587.2, CNPY3, AL035587.1.
- chr7:18,429,062–44,709,066, 495 genes, copy number 5–11 (broad region; genes not listed).
- chr7:64,500,825–70,838,013, 132 genes, copy number 5–6 (broad region; genes not listed).
- chr7:79,768,028–89,754,726, 84 genes, copy number 5–6 (broad region; genes not listed).
- chr7:142,695,699–159,233,377, 378 genes, copy number 5–9 (broad region; genes not listed).
- chr8:126,325,454–145,066,685, 352 genes, copy number 6–7 (broad region; genes not listed).
- chr9:8,936,079–10,830,308, 9 genes, copy number 5: AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1.
- chr9:12,098,660–15,146,401, 39 genes, copy number 5 (within-gene range 3–5): AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1.
- chr10:73,909,177–73,922,777, 2 genes, copy number 5: PLAU, C10orf55.
- chr10:80,407,829–80,535,942, 3 genes, copy number 6: PRXL2A, TSPAN14, AC021028.1.
- chr11:123,939,543–125,139,587, 70 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr12:66,767–22,690,665, 626 genes, copy number 5–8 (broad region; genes not listed).
- chr12:22,722,229–22,743,091, 2 genes, copy number 5: RPS27P22, AC084819.1.
- chr12:27,824,207–38,589,812, 146 genes, copy number 5 (broad region; genes not listed).
- chr12:62,466,817–72,670,758, 216 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:18,333,726–21,699,151, 202 genes, copy number 6 (broad region; genes not listed).
- chr14:35,044,907–35,537,054, 20 genes, copy number 6: FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2.
- chr14:40,954,693–56,427,032, 247 genes, copy number 5 (broad region; genes not listed).
- chr14:61,277,370–61,322,838, 2 genes, copy number 6: TMEM30B, AL359220.1.
- chr14:68,605,396–69,154,804, 19 genes, copy number 6: AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3, BANF1P1, ACTN1-AS1, RPS29P1, DCAF5, DDX18P1, Y_RNA, AL391262.1.
- chr15:92,393,881–101,933,350, 209 genes, copy number 5–6 (broad region; genes not listed).
- chr16:31,952,160–47,162,749, 228 genes, copy number 5 (broad region; genes not listed).
- chr16:47,196,311–47,263,500, 3 genes, copy number 5: AC007494.2, AC007494.3, AC007494.1.
- chr16:89,613,308–89,671,272, 3 genes, copy number 8: DPEP1, CHMP1A, SPATA33.
- chr18:25,953,216–35,966,118, 144 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr19:27,638,483–30,909,155, 68 genes, copy number 5–6 (broad region; genes not listed).
- chr20:6,065,966–6,123,030, 2 genes, copy number 5 (within-gene range 3–5): AL118505.1, FERMT1.

Autosomal genes at a single copy (total copy number 1): 5,630. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
